Gene-level copy-number profile of tumor specimen TCGA-04-1349-01A from TCGA case TCGA-04-1349, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.0 years (25,213 days).
Specimen TCGA-04-1349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.736806c4-db62-4e8f-8f4c-ec723295ea84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1349-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1f6fea8-7d6b-4dea-8ddd-dc86bb97f171

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,835; copy number 2: 21,002; copy number 3: 14,544; copy number 4: 18,239; copy number 5: 219; copy number 6: 1,951; copy number 7: 16; copy number 8: 74; copy number 9: 1,785; copy number 10: 82; copy number 11: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1349-01A-01D-0452-01): tumor purity 0.76, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,200 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:127,165,506–198,222,513, 1,278 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–21,523,783, 361 genes, copy number 6 (broad region; genes not listed).
- chr6:22,663,507–28,923,988, 246 genes, copy number 6 (broad region; genes not listed).
- chr7:156,388,922–159,233,377, 47 genes, copy number 6 (within-gene range 4–6): LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:33,604,856–34,039,104, 1 gene, copy number 10 (within-gene range 2–10): AF279873.3.
- chr8:33,859,480–33,860,223, 1 gene, copy number 10: AF279873.2.
- chr8:35,235,475–145,066,685, 1,726 genes, copy number 9 (broad region; genes not listed).
- chr10:106,970,021–113,353,484, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:58,920,639–59,586,943, 10 genes, copy number 6 (within-gene range 4–6): AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P.
- chr15:51,681,492–53,453,487, 44 genes, copy number 5 (within-gene range 4–5): SCG3, AC020892.1, AC020892.2, LYSMD2, TMOD2, AC026770.1, TMOD3, AC090971.5, Metazoa_SRP, AC090971.4, Y_RNA, AC090971.2, RNU6-90P, AC090971.1, AC090971.3, LEO1, MAPK6, MAPK6-DT, AC090970.2, AC090970.1, AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266, MYO5A, EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1.
- chr19:10,037,803–10,074,135, 1 gene, copy number 6 (within-gene range 4–6): C3P1.
- chr19:10,086,122–10,713,437, 44 genes, copy number 6–10: SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1.
- chr19:10,718,404–10,718,503, 1 gene, copy number 10: MIR638.
- chr19:12,751,702–19,358,754, 359 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr19:19,708,965–19,836,073, 12 genes, copy number 9 (within-gene range 4–9): AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1.

Autosomal genes at a single copy (total copy number 1): 1,835. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
